Somatic mutation profile of tumor specimen TARGET-10-PATNIA-09A (aliquot TARGET-10-PATNIA-09A-01D) from TARGET case TARGET-10-PATNIA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,401 days).
Specimen TARGET-10-PATNIA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd070f4d-d5e7-4481-8586-136c027ad976.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATNIA-10A (Blood Derived Normal), aliquot TARGET-10-PATNIA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/639d9941-23cf-48f5-ae08-5710467fe7b0

The open-access MAF lists 25 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 4, Intron 4, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZH2 | c.2182T>C p.Y728H (on ENST00000460911 / NM_001203247.2; = p.Y733H on NM_004456.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57451756, COSV57465403; called by muse, mutect2, varscan2
- FAP | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs746854357, COSV51861034, COSV51868981; called by muse, mutect2, varscan2
- MED12 | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 25/44 reads (57%) | catalogued as COSV61359729; called by muse, mutect2, varscan2
- MGAT5 | c.556T>C p.F186L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.943); catalogued as COSV56102228; called by muse, mutect2, varscan2
- NOTCH1 | c.7207C>T p.Q2403* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV53088547; called by muse, mutect2, varscan2
- PTEN | c.697delinsGGCCTCAAGGGGTA p.R233Gfs*5 | Nonsense Mutation (INS) | VAF 28/33 reads (85%) | catalogued as CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; called by pindel, varscan2*
- PTEN | c.699_700delinsGGGAACCCCCACGTAA p.R234Gfs*5 | Nonsense Mutation (INS) | VAF 27/31 reads (87%) | catalogued as COSV64296235; called by pindel, varscan2*
- SP140L | c.887_888del p.V296Gfs*20 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs767306474; called by pindel, varscan2
- TTC12 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368333321, COSV100133055; called by muse, mutect2, varscan2
- DNM2 | c.189_190del p.V64Hfs*31 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by pindel*, varscan2
- ADCY9 | c.1899C>T p.C633= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs143099437; called by muse, mutect2, varscan2
- AMIGO3 | c.1110C>T p.S370= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs761947662; called by muse, mutect2, varscan2
- IGLV2-23 | c.84C>T p.S28= | Silent (SNP) | VAF 38/69 reads (55%) | called by muse, mutect2, varscan2
- KRT12 | c.342G>A p.S114= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as rs938238185, COSV52430850; called by muse, mutect2, varscan2
- L1CAM | c.2253C>T p.R751= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs782035973, COSV100649451; called by muse, mutect2, varscan2
- PHYHIP | c.243C>T p.R81= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV58688216; called by muse, mutect2, varscan2
- SLC6A2 | c.156C>T p.D52= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99574650; called by muse, mutect2, varscan2
- SOST | c.108C>T p.I36= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs375834623; called by muse, mutect2, varscan2
- CAPN6 | c.-1T>G | 5'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- CXCL12 | c.179+48C>T | Intron (SNP) | VAF 12/40 reads (30%) | catalogued as rs371480399; called by muse, mutect2, varscan2
- MED10 | c.-49C>A | 5'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2
- NUB1 | c.1742-57A>G | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- RAB28 | c.*12T>A | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- RFC1 | c.331+771T>G | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as rs535060901; called by muse, mutect2, varscan2
- SH3GLB2 | c.562-121C>T | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as rs952915175; called by muse, mutect2, varscan2
